Somatic mutation profile of tumor specimen TCGA-A6-A565-01A (aliquot TCGA-A6-A565-01A-31D-A28G-10) from TCGA case TCGA-A6-A565, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 34.3 years (12,526 days).
Specimen TCGA-A6-A565-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a02ec442-9756-4fdc-a87f-47321691ed77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-A565-10A (Blood Derived Normal), aliquot TCGA-A6-A565-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/214fd7e0-bb21-4c80-a40a-068a82b6beaf

The open-access MAF lists 401 somatic variants for this specimen: 287 protein-altering or splice-affecting, 90 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 220, Silent 90, Frame Shift Del 37, Nonsense Mutation 16, 3'UTR 12, Frame Shift Ins 7, Intron 7, Splice Region 4, RNA 3, Splice Site 2, 5'UTR 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.1834C>T p.Q612* | Nonsense Mutation (SNP) | VAF 3/50 reads (6%) | catalogued as rs1057517700; ClinVar: pathogenic; called by muse, mutect2
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 24/177 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DOK7 | c.1263del p.S422Hfs*34 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | catalogued as rs606231129; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SMAD2 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 6/143 reads (4%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50994862; called by muse, mutect2
- SPG11 | c.3075del p.E1026Sfs*12 | Frame Shift Del (DEL) | VAF 23/199 reads (12%) | catalogued as rs312262752; ClinVar: pathogenic; called by mutect2, varscan2
- AAK1 | c.1855C>G p.L619V | Missense Mutation (SNP) | VAF 18/235 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs746057391, COSV101275857; called by muse, mutect2
- ACSS2 | c.806del p.P269Qfs*69 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as rs745681981, COSV53623223; called by pindel, varscan2
- ADCY5 | c.2164C>T p.R722C | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as rs1412031145, COSV59194201; called by muse, mutect2
- ADCY6 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100326412; called by muse, mutect2
- ADGRB2 | c.4580C>T p.P1527L (on ENST00000373658 / NM_001364857.2; = p.P1526L on NM_001294335.2) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV57072067; called by muse, mutect2
- ADGRB3 | c.2914G>T p.G972* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | catalogued as COSV99483711; called by muse, mutect2
- ALDH1A3 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs567004839, COSV60901605; called by muse, mutect2
- ALPP | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV67398383; called by muse, mutect2
- ANK2 | c.1397C>T p.T466M | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs786205722, COSV52161357; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD40 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99560381; called by muse, mutect2
- ANKS1A | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 31/142 reads (22%) | catalogued as COSV100832969; called by muse, mutect2, varscan2
- AP5Z1 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs763884027; called by muse, mutect2, varscan2
- ARL13B | c.761C>T p.T254M (on ENST00000394222 / NM_001174150.2; = p.T147M on NM_144996.4) | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV57397450; called by muse, mutect2
- ARNTL | c.1372G>T p.A458S (on ENST00000403290 / NM_001297719.2; = p.A457S on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62986743; called by muse, mutect2, varscan2
- ATG16L1 | c.1422G>T p.W474C (on ENST00000392017 / NM_030803.7; = p.W455C on NM_017974.4) | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61465834; called by muse, mutect2
- ATP2B3 | c.3220G>A p.G1074R | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs1557017618, COSV54848874; called by muse, mutect2
- ATP7A | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV58447011; called by muse, mutect2
- BEST1 | c.592G>T p.G198* | Nonsense Mutation (SNP) | VAF 7/127 reads (6%) | catalogued as COSV57121659; called by muse, mutect2
- BICD2 | c.2384G>A p.R795Q | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1473987839; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP1 | c.1789A>G p.K597E | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.118); catalogued as COSV100109094; called by muse, mutect2, varscan2
- BRI3BP | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as COSV58295406; called by muse, mutect2, varscan2
- BRINP1 | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.535); catalogued as rs557929677; called by muse, mutect2, varscan2
- C2CD2L | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV100371078; called by mutect2, varscan2
- C2orf42 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769630580, COSV100033707; called by muse, mutect2, varscan2
- C9orf50 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs535635348, COSV100992334; called by muse, mutect2, varscan2
- CASKIN2 | c.1016del p.P339Rfs*95 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | catalogued as COSV100050703; called by mutect2, pindel, varscan2
- CCDC168 | c.21051del p.F7017Lfs*25 | Frame Shift Del (DEL) | VAF 13/79 reads (16%) | catalogued as rs397851855; called by mutect2, varscan2
- CDH23 | c.8498G>A p.R2833H | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as rs534575559, COSV99819019; called by muse, mutect2, varscan2
- CDK5RAP1 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766215061, COSV59427033; called by muse, mutect2, varscan2
- CDON | c.3589G>A p.V1197I | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs911339564, COSV99700453; called by muse, mutect2
- CELF2 | c.851C>T p.A284V (on ENST00000416382 / NM_001025077.3; = p.A291V on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.874); catalogued as rs1210960574, COSV59973362; called by muse, mutect2, varscan2
- CGNL1 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs763750155, COSV55571283; called by muse, mutect2, varscan2
- CLCA2 | c.1985-1G>A p.X662_splice | Splice Site (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100991357; called by muse, mutect2
- COG1 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100245140; called by muse, mutect2
- COL10A1 | c.2030T>C p.V677A | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as rs1157359218, CM151770, COSV99684074; called by muse, mutect2, varscan2
- COPA | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54109756, COSV99614808; called by muse, mutect2, varscan2
- CPSF6 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.375); catalogued as rs777748091, COSV99879378; called by muse, mutect2
- CSMD2 | c.1735T>C p.F579L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.992); catalogued as COSV99586327; called by muse, mutect2
- CSMD3 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.19); catalogued as COSV99825556; called by muse, mutect2
- DCHS2 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.019); catalogued as rs963522517, COSV59727814; called by muse, mutect2, varscan2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 8/57 reads (14%) | catalogued as rs759023106; called by mutect2, varscan2
- DDX43 | c.1714G>A p.V572I | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as rs372223699, COSV64812208; called by muse, mutect2, varscan2
- DMAP1 | c.402G>T p.Q134H | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV100261560; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | catalogued as rs782552436; called by mutect2, pindel
- DOK7 | c.787C>A p.L263M | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV100403154; called by muse, mutect2
- DRD5 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs867973828, COSV58577896; called by muse, mutect2
- DUOX2 | c.494C>A p.P165H | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1431568651, COSV100545752; called by muse, mutect2
- DUS4L-BCAP29 | c.16A>G p.M6V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as rs1340207083, COSV51752389; called by muse, varscan2
- EIF3A | c.2465T>C p.M822T | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV64963730; called by muse, mutect2
- ELMOD1 | c.253A>G p.M85V | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs760709555; called by muse, mutect2
- ELOA | c.1609C>T p.R537* | Nonsense Mutation (SNP) | VAF 6/97 reads (6%) | catalogued as rs914269592, COSV101403611; called by muse, mutect2
- EMID1 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as rs745674433; called by muse, mutect2
- EMILIN2 | c.2767G>A p.V923I | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.827); catalogued as rs780356221, COSV99598141; called by muse, mutect2
- EOLA1 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 38/648 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV63734128; called by muse, mutect2
- EPHA8 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1394031937, COSV51263170; called by muse, mutect2
- ERN2 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 17/288 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV56833909, COSV56838093; called by muse, mutect2
- ETFB | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV58536107; called by muse, mutect2, varscan2
- EXOC4 | c.2113A>G p.S705G | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV54099573; called by muse, mutect2
- FANCL | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99287261; called by muse, mutect2
- FAT2 | c.5554G>A p.A1852T | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); catalogued as COSV99941746; called by muse, mutect2
- FAT3 | c.11401G>A p.E3801K | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs1435237876, COSV53118159, COSV53159525; called by muse, mutect2
- FBLN1 | c.1313C>A p.S438* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV53048337; called by muse, mutect2, varscan2
- FBXL14 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs140261682; called by mutect2, varscan2
- FBXL20 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.734); catalogued as COSV52904551; called by muse, mutect2
- FCRL2 | c.1440G>A p.M480I | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100829834; called by muse, mutect2, varscan2
- FIGNL2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs781164340; called by muse, mutect2
- FKBP1C | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1561983968; called by muse, mutect2
- FOXD3 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100942795; called by muse, mutect2
- GAB4 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs745520066, COSV68753142; called by muse, mutect2
- GJC3 | c.303G>A p.W101* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as COSV57209802; called by muse, mutect2, varscan2
- GRIN2D | c.2564C>T p.A855V | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as rs1377932302; called by muse, mutect2
- GTF3C1 | c.3538dup p.E1180Gfs*17 | Frame Shift Ins (INS) | VAF 9/98 reads (9%) | catalogued as rs1375103432; called by mutect2, pindel
- GYS2 | c.1336C>T p.H446Y | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM980967, COSV53927357, COSV99679450; called by muse, mutect2
- HAPLN4 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768177678, COSV52269445; called by mutect2, varscan2
- HCFC1 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60072829; called by muse, mutect2, varscan2
- HIRA | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV54272265; called by muse, mutect2
- HNRNPDL | c.867dup p.L290Ifs*15 | Frame Shift Ins (INS) | VAF 12/124 reads (10%) | catalogued as rs1202858345; called by mutect2, varscan2
- IGF1R | c.2827G>A p.A943T | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as rs761063787, COSV51357468; called by muse, mutect2, varscan2
- IL6R | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs868345266, COSV59815718; called by muse, mutect2
- INPP5B | c.1501C>T p.R501* (on ENST00000373023; = p.R421* on NM_005540.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 9/148 reads (6%) | catalogued as rs779148739; called by muse, mutect2
- INPP5J | c.2368G>A p.V790I (on ENST00000331075 / NM_001284285.2; = p.V422I on NM_001002837.2) | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV53209897; called by muse, mutect2
- ITPR2 | c.5749A>G p.I1917V | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.378); catalogued as rs1565554117; called by muse, mutect2
- IVL | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.608); catalogued as COSV100908081; called by muse, mutect2
- KAZN | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101054779; called by muse, mutect2, varscan2
- KCNE5 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750897913, CM142060, COSV64508436; called by muse, mutect2, varscan2
- KCNIP2 | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 12/103 reads (12%) | catalogued as COSV99493156; called by muse, mutect2, varscan2
- KCNN3 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as rs771961515, COSV55221106, COSV55222089; called by muse, mutect2, varscan2
- KCNQ4 | c.1963G>A p.V655M | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.113); catalogued as COSV100714286; called by muse, mutect2
- KDM5C | c.730A>G p.K244E | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV100948797; called by muse, mutect2, varscan2
- KHDC1 | c.440C>T p.P147L (on ENST00000370384 / NM_001251874.2; = p.P74L on NM_030568.5) | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100001717; called by muse, mutect2
- KLHL9 | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs1374599886, COSV100757071; called by muse, mutect2
- KMT2D | c.15790T>C p.W5264R | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56445603; called by muse, mutect2
- KPNA2 | c.80T>C p.M27T | Missense Mutation (SNP) | VAF 38/452 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs782494077, COSV100388671; called by muse, mutect2
- L3MBTL2 | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.205); catalogued as rs374138813; called by muse, mutect2, varscan2
- LAG3 | c.902C>A p.P301H | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99179882; called by muse, mutect2
- LAMB3 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.076); catalogued as rs144249951, COSV61917846; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 13/128 reads (10%) | catalogued as COSV65473126, COSV65473260; called by mutect2, pindel
- LRRC71 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100503816; called by muse, mutect2
- MANSC1 | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 14/157 reads (9%) | catalogued as COSV101115731; called by muse, mutect2
- MARF1 | c.2720del p.K907Sfs*6 | Frame Shift Del (DEL) | VAF 20/229 reads (9%) | catalogued as rs1303520043; called by mutect2, pindel
- MBD1 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1428545515, COSV54001990; called by muse, mutect2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MED12 | c.4507C>A p.L1503I | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61341491; called by muse, mutect2
- MMEL1 | c.84del p.L29Cfs*8 | Frame Shift Del (DEL) | VAF 13/96 reads (14%) | catalogued as rs1168749408; called by mutect2, pindel, varscan2
- MMGT1 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 16/240 reads (7%) | catalogued as rs377059218, COSV60003158; called by muse, mutect2
- MMP14 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as rs748601843; called by muse, mutect2
- MPDU1 | c.110G>A p.C37Y | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51468368; called by muse, mutect2, varscan2
- MTNR1B | c.908T>C p.L303P | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1359258912; called by muse, mutect2
- MYO7B | c.4988T>G p.L1663R | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV67348220; called by muse, mutect2
- NAA25 | c.554T>C p.V185A | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as rs932403815; called by muse, mutect2
- NAPSA | c.1091C>A p.P364H | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53797604; called by muse, mutect2
- NBEAL2 | c.6868G>A p.G2290R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99434581; called by muse, mutect2, varscan2
- NCAM1 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as rs782700835, COSV57517344; called by muse, mutect2
- NDUFS8 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); catalogued as rs758247003, CM134822, COSV50291253; called by muse, mutect2
- NEB | c.11198G>A p.G3733E | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.894); catalogued as COSV51421393; called by muse, mutect2
- NECAB3 | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.089); catalogued as COSV55776420; called by muse, mutect2, varscan2
- NEFM | c.2528_2529insT p.K843Nfs*4 | Frame Shift Ins (INS) | VAF 19/184 reads (10%) | catalogued as COSV99646968; called by mutect2, pindel, varscan2
- NET1 | c.1038A>G p.I346M (on ENST00000355029 / NM_001047160.3; = p.I292M on NM_005863.5) | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV100742260; called by muse, mutect2
- NEUROD6 | c.248del p.K83Rfs*35 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | catalogued as rs752284115; called by mutect2, varscan2
- NOTCH3 | c.5638G>A p.V1880I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99655955; called by muse, mutect2, varscan2
- ONECUT2 | c.1307T>C p.L436P | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV101525686; called by muse, mutect2
- OR10A3 | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749672587, COSV100660219; called by muse, mutect2
- OR10G3 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs536842323, COSV57810985; called by muse, mutect2, varscan2
- OR52L1 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs762784705, COSV59985620; called by muse, mutect2
- OR6C75 | c.826A>G p.N276D | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as COSV100595252; called by muse, mutect2
- ORAI1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782538669; called by muse, mutect2
- PANK4 | c.2037G>A p.V679= | Splice Region (SNP) | VAF 16/153 reads (10%) | catalogued as rs1418528234, COSV99615575; called by muse, mutect2, varscan2
- PCDHA8 | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.23); catalogued as COSV65325316; called by muse, mutect2
- PCDHGB6 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53958775; called by muse, mutect2, varscan2
- PDLIM5 | c.218G>A p.C73Y | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs1163596522; called by muse, mutect2
- PDLIM7 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as rs1258569749, COSV62883326; called by muse, mutect2, varscan2
- PER1 | c.1396del p.L466* | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | catalogued as rs773913770; called by mutect2, pindel, varscan2
- PEX11G | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.748); catalogued as rs199832453, COSV99675945; called by muse, mutect2, varscan2
- PFAS | c.2725G>A p.D909N | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs944192787, COSV58980705; called by muse, mutect2
- PIK3C2G | c.2902C>T p.R968C (on ENST00000676171; = p.R927C on NM_004570.5) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368805708; called by muse, mutect2, varscan2
- PISD | c.1097G>A p.R366H (on ENST00000439502 / NM_001326412.1; = p.R332H on NM_014338.3) | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs567105342, COSV56718939; called by muse, mutect2
- POLK | c.1249A>T p.S417C | Missense Mutation (SNP) | VAF 14/235 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54035644; called by muse, mutect2
- POTEF | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 36/324 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV62541466; called by muse, mutect2, varscan2
- POU2F1 | c.2089G>A p.A697T (on ENST00000541643 / NM_001365848.1; = p.A720T on NM_002697.4) | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as rs561712054, COSV54821854; called by muse, mutect2
- PPRC1 | c.4786G>A p.A1596T | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.465); catalogued as COSV99531320; called by muse, mutect2
- PRDM2 | c.2278A>G p.K760E | Missense Mutation (SNP) | VAF 29/306 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.728); catalogued as rs1157598246; called by muse, mutect2, varscan2
- PSCA | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1280649395; called by muse, mutect2
- PTPRN2 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs146528593; called by mutect2, varscan2
- PXN | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs1364489163, COSV57219063; called by muse, mutect2, varscan2
- PYGB | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs776622403, COSV99404873; called by muse, mutect2
- R3HDM1 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs747738172, COSV51525391; called by muse, mutect2, varscan2
- RADIL | c.2642del p.P881Lfs*110 | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | catalogued as rs767679528; called by mutect2, pindel
- RANBP10 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs764159885, COSV100449133; called by muse, mutect2
- RC3H2 | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 18/112 reads (16%) | catalogued as COSV59013618; called by muse, mutect2, varscan2
- RGS7 | c.1182del p.S395Vfs*17 | Frame Shift Del (DEL) | VAF 11/108 reads (10%) | catalogued as COSV100468583, COSV58548022; called by mutect2, varscan2
- RNF144B | c.233T>C p.M78T | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs767789668; called by mutect2, varscan2
- RNF213 | c.6101G>A p.R2034Q | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs918889499, COSV60407638; called by muse, mutect2, varscan2
- RNF40 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.99); catalogued as rs755165767; called by muse, mutect2
- RORA | c.519G>C p.Q173H (on ENST00000335670 / NM_134261.3; = p.Q198H on NM_002943.3) | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.689); catalogued as rs1214624353; called by muse, mutect2
- ROS1 | c.4706G>A p.R1569Q | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs141448347; called by muse, mutect2
- RYR3 | c.11195G>A p.R3732H (on ENST00000389232; = p.R3733H on NM_001036.6) | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.54); catalogued as rs374140172; ClinVar: uncertain significance; called by muse, mutect2
- SCN1A | c.1550A>G p.E517G | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs866861536; called by muse, mutect2
- SCNN1G | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55599199; called by muse, mutect2, varscan2
- SCP2 | c.1549-1G>T p.X517_splice | Splice Site (SNP) | VAF 5/47 reads (11%) | catalogued as COSV101026837; called by muse, mutect2, varscan2
- SECISBP2L | c.169T>C p.C57R | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99959893; called by muse, mutect2
- SEMA6C | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs373129237; called by muse, mutect2, varscan2
- SEPTIN6 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.097); catalogued as COSV100595393, COSV59714363; called by muse, mutect2
- SH3TC1 | c.2227G>A p.G743S | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs1314933239, COSV99794443; called by muse, mutect2
- SHANK2 | c.4687T>C p.Y1563H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.334); catalogued as rs539921607; called by muse, mutect2
- SLC19A1 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1310333627; called by muse, mutect2, varscan2
- SLC45A1 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs12074190, COSV99238326; called by muse, mutect2, varscan2
- SNX14 | c.2557G>A p.D853N (on ENST00000314673 / NM_001350535.1; = p.D800N on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59016694; called by muse, mutect2
- SPATA32 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.056); catalogued as rs765864683, COSV59303287; called by muse, mutect2
- SS18L1 | c.916+1del | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | catalogued as rs1204381214; called by mutect2, varscan2
- STON1 | c.1694G>A p.C565Y | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV59127730; called by muse, mutect2, varscan2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs747003550; called by mutect2, varscan2
- SWAP70 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs763528333, COSV59666937; called by muse, mutect2, varscan2
- SYNE2 | c.15962A>C p.Q5321P | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1456319728, COSV100646753; called by muse, mutect2
- TBC1D32 | c.1519C>A p.Q507K | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as COSV51544371; called by muse, mutect2
- TCF20 | c.2884C>A p.R962S | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs754587682, COSV100166279, COSV59493571; called by muse, mutect2, varscan2
- TCP1 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs1207751364; called by muse, mutect2
- TDP1 | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV100187579; called by muse, mutect2
- TNK2 | c.1522del p.Q508Sfs*3 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | catalogued as rs754147115; called by mutect2, varscan2
- TNS1 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 7/152 reads (5%) | catalogued as COSV50697321, COSV99412224; called by muse, mutect2
- TNXB | c.6010G>A p.G2004S (on ENST00000647633; = p.G1757S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.573); catalogued as rs747658329; called by muse, mutect2, varscan2
- TRIM35 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.271); catalogued as rs1339952022, COSV59523107; called by muse, mutect2
- TRPM3 | c.2701C>T p.R901C (on ENST00000357533 / NM_001366142.2; = p.R744C on NM_020952.6) | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.676); catalogued as rs372170254; called by muse, mutect2, varscan2
- TTN | c.79631G>A p.R26544Q (on ENST00000591111; = p.R19120Q on NM_003319.4) | Missense Mutation (SNP) | VAF 12/136 reads (9%) | PolyPhen benign (0); catalogued as rs371516793; called by muse, mutect2, varscan2
- TUBG2 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as rs372512326; called by muse, mutect2
- UNC13C | c.3164C>T p.A1055V | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.194); catalogued as COSV52856270, COSV52878610; called by muse, mutect2
- UNC5B | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1253641274, COSV100100253; called by muse, mutect2
- UNC79 | c.4718C>A p.A1573D (on ENST00000393151 / NM_001346218.2; = p.A1396D on NM_020818.5) | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as COSV56390307; called by muse, mutect2
- USP7 | c.3010G>A p.G1004R | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61214236; called by muse, mutect2
- VAPA | c.608T>C p.L203P (on ENST00000400000 / NM_194434.3; = p.L248P on NM_003574.6) | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs773854854; called by muse, mutect2
- VWA7 | c.1448A>G p.K483R | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.124); catalogued as rs1180068551; called by muse, mutect2, varscan2
- WRNIP1 | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs369024379; called by muse, mutect2, varscan2
- XK | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.077); catalogued as COSV66120416; called by muse, mutect2
- ZC3HAV1 | c.435del p.F145Lfs*49 | Frame Shift Del (DEL) | VAF 27/204 reads (13%) | catalogued as rs1363033923; called by mutect2, pindel, varscan2
- ZDHHC6 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748119885; called by muse, mutect2, varscan2
- ZFAND5 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs1419561932, COSV99428533; called by muse, mutect2
- ZFHX3 | c.4136C>T p.T1379M | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.09); catalogued as rs753592536, COSV51708511; called by muse, mutect2
- ZNF35 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99939966; called by muse, mutect2
- ZNF585A | c.1573A>G p.N525D (on ENST00000292841 / NM_001288800.2; = p.N470D on NM_152655.3) | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.099); catalogued as rs1478858196; called by muse, mutect2
- ZNF585B | c.1214C>T p.T405I | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100459302; called by muse, mutect2
- ZNF699 | c.1694G>A p.G565E | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV104393999; called by muse, mutect2
- ZNF777 | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs746782008, COSV56097040, COSV56099600; called by muse, mutect2
- ZYX | c.1564C>T p.R522* | Nonsense Mutation (SNP) | VAF 14/166 reads (8%) | catalogued as rs750192633, COSV99313526; called by muse, mutect2
- ADTRP | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AGAP3 | c.2386A>G p.M796V (on ENST00000622464; = p.M832V on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- AGO3 | c.2233T>C p.Y745H | Missense Mutation (SNP) | VAF 26/313 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.146); called by muse, mutect2
- AHNAK | c.8354A>C p.D2785A | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.082); called by muse, mutect2
- ANGPTL1 | c.950dup p.W318Lfs*22 | Frame Shift Ins (INS) | VAF 9/65 reads (14%) | called by mutect2, pindel
- ASS1 | c.412del p.Q138Rfs*2 | Frame Shift Del (DEL) | VAF 15/98 reads (15%) | called by mutect2, pindel, varscan2
- ATL3 | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by muse, mutect2
- BCORL1 | c.3496del p.A1166Lfs*56 | Frame Shift Del (DEL) | VAF 16/152 reads (11%) | called by mutect2, pindel
- BCS1L | c.937C>A p.L313I | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- C8B | c.737A>C p.E246A | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.138); called by muse, mutect2
- CATSPERB | c.2158T>C p.Y720H | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CCDC77 | c.1034A>G p.Y345C | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); called by muse, mutect2
- CCNK | c.196C>T p.L66= | Splice Region (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- CCNT2 | c.398T>A p.V133D | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- CELSR1 | c.1841del p.G614Afs*54 | Frame Shift Del (DEL) | VAF 7/71 reads (10%) | called by mutect2, pindel
- CENPF | c.3529T>G p.S1177A | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CKAP5 | c.3116A>G p.Q1039R | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CLCC1 | c.1229G>A p.G410D (on ENST00000356970 / NM_001377464.1; = p.G360D on NM_015127.5) | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); called by muse, mutect2
- CNOT6L | c.1533G>A p.W511* (on ENST00000504123 / NM_001286790.2; = p.W506* on NM_144571.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 30/369 reads (8%) | called by muse, mutect2
- CROCC2 | c.1919T>C p.L640P | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- CTSL | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); called by muse, mutect2
- CWF19L1 | c.1140G>T p.E380D | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.083); called by muse, mutect2
- CYP4B1 | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DNAJC10 | c.2242T>A p.F748I | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.06); called by muse, mutect2
- DYSF | c.108A>C p.K36N | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.912); called by muse, mutect2
- EMID1 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM107B | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.005); called by muse, mutect2
- FAM186A | c.2261del p.K754Rfs*2 | Frame Shift Del (DEL) | VAF 9/80 reads (11%) | called by mutect2, pindel, varscan2
- FCSK | c.3064G>A p.A1022T | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- GID4 | c.408dup p.N137Efs*26 | Frame Shift Ins (INS) | VAF 7/63 reads (11%) | called by mutect2, pindel, varscan2
- GRIP2 | c.1681del p.L561Sfs*95 (on ENST00000619221; = p.L464Sfs*95 on NM_001080423.4) | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | called by mutect2, pindel, varscan2
- GTF3A | c.569T>C p.V190A | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2
- HGH1 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.951); called by muse, mutect2
- HNRNPH1 | c.1103G>T p.S368I | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.208); called by muse, mutect2
- IFNAR1 | c.458G>A p.S153N | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.42); called by muse, mutect2
- IGHE | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- IPO8 | c.2775G>T p.E925D | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2
- KIAA1671 | c.4168C>A p.Q1390K | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- KRT7 | c.1337G>A p.S446N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LRP4 | c.5358G>A p.M1786I | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- MOCOS | c.2227A>G p.N743D | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MUC5B | c.14732G>A p.S4911N | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- MYH4 | c.2942del p.N981Tfs*16 | Frame Shift Del (DEL) | VAF 16/154 reads (10%) | called by mutect2, pindel, varscan2
- MYO3B | c.3719C>T p.A1240V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO9A | c.1986G>A p.K662= | Splice Region (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- NCKAP5L | c.2172del p.I725Yfs*12 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- NIN | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2
- NISCH | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2
- NPTX2 | c.502del p.E168Sfs*35 | Frame Shift Del (DEL) | VAF 16/154 reads (10%) | called by mutect2, pindel
- NR4A2 | c.325del p.Q109Sfs*5 | Frame Shift Del (DEL) | VAF 12/116 reads (10%) | called by mutect2, pindel
- NSF | c.1666del p.I556Lfs*18 | Frame Shift Del (DEL) | VAF 14/157 reads (9%) | called by mutect2, pindel
- PHACTR4 | c.330del p.I111* (on ENST00000373839 / NM_001350159.2; = p.I121* on NM_023923.4) | Frame Shift Del (DEL) | VAF 11/95 reads (12%) | called by pindel, varscan2
- PLXNB1 | c.2694del p.L900Sfs*25 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel, varscan2
- POLG | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRR14L | c.2231dup p.E745Gfs*4 | Frame Shift Ins (INS) | VAF 12/117 reads (10%) | called by mutect2, pindel
- PSD2 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PSMD2 | c.2283G>A p.M761I | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.48); called by muse, mutect2
- PTPRK | c.2050C>T p.P684S | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RALGDS | c.2195A>G p.D732G | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); called by muse, mutect2
- RBM15 | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RNF167 | c.683_685del p.D228del | In Frame Del (DEL) | VAF 12/87 reads (14%) | called by pindel, varscan2
- SDK2 | c.3971del p.P1324Lfs*69 | Frame Shift Del (DEL) | VAF 16/160 reads (10%) | called by mutect2, varscan2
- SETD1A | c.530T>C p.M177T | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.239); called by muse, mutect2
- SGO2 | c.2237del p.L746* | Frame Shift Del (DEL) | VAF 11/95 reads (12%) | called by mutect2, pindel, varscan2
- SPATA31E1 | c.4034A>T p.H1345L | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.553); called by muse, mutect2
- SPP2 | c.453del p.F151Lfs*24 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel, varscan2
- SPRED1 | c.234del p.D79Tfs*42 | Frame Shift Del (DEL) | VAF 7/86 reads (8%) | called by mutect2, pindel
- SPTA1 | c.1502del p.N501Tfs*33 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel
- STAG1 | c.2869C>T p.R957C | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TET1 | c.3491C>T p.T1164I | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- THSD7A | c.4105dup p.C1369Lfs*5 | Frame Shift Ins (INS) | VAF 10/99 reads (10%) | called by mutect2, pindel, varscan2
- TMCC3 | c.1103A>C p.Q368P | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TMPRSS2 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.292); called by muse, mutect2
- TNS1 | c.7G>A p.V3M | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.204); called by muse, mutect2
- TOX3 | c.1057A>T p.T353S | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by muse, mutect2
- TRAF2 | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- TTC7B | c.2468C>T p.T823I | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- VPS13B | c.11961del p.S3988Pfs*25 | Frame Shift Del (DEL) | VAF 14/133 reads (11%) | called by mutect2, pindel, varscan2
- ZBTB8OS | c.158+5G>A | Splice Region (SNP) | VAF 13/105 reads (12%) | called by muse, mutect2, varscan2
- ZPBP | c.106C>A p.L36M | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- ACACB | c.3645C>T p.S1215= | Silent (SNP) | VAF 10/129 reads (8%) | catalogued as rs780338785, COSV100622905; called by muse, mutect2
- ADAM29 | c.798G>A p.V266= | Silent (SNP) | VAF 17/178 reads (10%) | called by muse, mutect2
- AGA | c.366A>G p.T122= | Silent (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- ANKIB1 | c.2991A>G p.A997= | Silent (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- ANXA8 | c.279G>A p.P93= | Silent (SNP) | VAF 122/1278 reads (10%) | catalogued as rs1383554593; called by muse, mutect2
- AOC1 | c.837G>A p.P279= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as rs967331841; called by muse, mutect2, varscan2
- ATP2B3 | c.2877G>A p.A959= | Silent (SNP) | VAF 12/200 reads (6%) | catalogued as rs781883776, COSV54848861, COSV54858164; called by muse, mutect2
- ATP5F1C | c.405C>T p.D135= | Silent (SNP) | VAF 8/119 reads (7%) | catalogued as rs1309050141; called by muse, mutect2
- ATP6V0C | c.420G>A p.V140= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99565620; called by mutect2, varscan2
- BGN | c.495C>T p.R165= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as COSV100525088; called by muse, mutect2
- CABIN1 | c.2604G>A p.Q868= | Silent (SNP) | VAF 14/155 reads (9%) | called by muse, mutect2
- CAPN14 | c.1443C>T p.H481= | Silent (SNP) | VAF 20/236 reads (8%) | called by muse, mutect2
- CAPN6 | c.1617A>G p.P539= | Silent (SNP) | VAF 14/169 reads (8%) | catalogued as COSV100136709; called by muse, mutect2
- CCDC86 | c.1032C>T p.T344= | Silent (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- CCDC88C | c.4878C>T p.N1626= | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as rs1264045241, COSV57796838; called by muse, mutect2
- CDH11 | c.1662C>T p.Y554= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs200486624, COSV99217300; called by muse, mutect2, varscan2
- CERS2 | c.378G>A p.R126= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99643823; called by muse, mutect2, varscan2
- CLCN3 | c.189C>T p.G63= | Silent (SNP) | VAF 24/436 reads (6%) | called by muse, mutect2
- CLEC4M | c.252C>T p.S84= | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as rs376354063; called by muse, mutect2
- CMYA5 | c.12081C>T p.S4027= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs767267922, COSV69745647; called by muse, mutect2
- COL24A1 | c.2130T>C p.P710= | Silent (SNP) | VAF 7/143 reads (5%) | catalogued as COSV100992914; called by muse, mutect2
- CSAD | c.1119C>T p.G373= (on ENST00000444623 / NM_001244705.2; = p.G400= on NM_015989.5) | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs1016029539, COSV57241577; called by muse, mutect2
- CYP26C1 | c.180C>T p.G60= | Silent (SNP) | VAF 9/141 reads (6%) | catalogued as COSV99591478; called by muse, mutect2
- CYP2A7 | c.1017G>A p.R339= | Silent (SNP) | VAF 17/198 reads (9%) | catalogued as rs754344920; called by muse, mutect2
- DDX58 | c.381G>T p.L127= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs997925025, COSV65882717; called by muse, mutect2, varscan2
- EIF3I | c.303T>C p.F101= | Silent (SNP) | VAF 8/152 reads (5%) | catalogued as COSV100557113; called by muse, mutect2
- EYS | c.3417T>C p.D1139= | Silent (SNP) | VAF 17/220 reads (8%) | catalogued as rs1238692406; ClinVar: likely benign; called by muse, mutect2
- FADS1 | c.858C>T p.D286= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as rs1565320243, COSV100650204; called by muse, mutect2
- GABBR2 | c.786A>G p.K262= | Silent (SNP) | VAF 14/188 reads (7%) | catalogued as COSV52302742; called by muse, mutect2
- HDHD5 | c.750T>C p.F250= (on ENST00000336737 / NM_033070.3; = p.F220= on NM_017829.5) | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV99324495; called by muse, mutect2
- IMP3 | c.120G>A p.Q40= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs1345910278, COSV100145728; called by mutect2, varscan2
- ING3 | c.639T>C p.I213= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as rs1252398600, COSV59951131; called by muse, mutect2
- KCNC3 | c.384C>T p.Y128= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100979175; called by muse, mutect2
- KCNMA1 | c.360C>T p.H120= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV54251780; called by muse, mutect2, varscan2
- KIF16B | c.852C>T p.N284= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as rs541939415, COSV61706823; called by muse, mutect2
- L1TD1 | c.1875C>T p.I625= | Silent (SNP) | VAF 28/270 reads (10%) | called by muse, mutect2, varscan2
- LCN6 | c.108C>T p.Y36= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs149829162; called by muse, mutect2, varscan2
- MANBA | c.2661C>T p.D887= (on ENST00000642252; = p.D841= on NM_005908.4) | Silent (SNP) | VAF 18/237 reads (8%) | called by muse, mutect2
- MDC1 | c.4113T>C p.P1371= | Silent (SNP) | VAF 22/148 reads (15%) | catalogued as COSV64524864; called by muse, mutect2, varscan2
- MDM1 | c.306T>C p.V102= | Silent (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- MEGF10 | c.2703C>T p.V901= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as rs758284831, COSV57249271; called by muse, mutect2
- MEGF8 | c.7938T>C p.I2646= (on ENST00000251268 / NM_001271938.2; = p.I2579= on NM_001410.3) | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV52086982; called by muse, mutect2, varscan2
- MOGAT3 | c.645C>T p.F215= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as rs186699255, COSV56172807; called by muse, mutect2, varscan2
- MYBPC3 | c.1335G>A p.T445= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs727503205; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEXMIF | c.4233T>G p.G1411= | Silent (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- PCDHA6 | c.1509G>A p.A503= | Silent (SNP) | VAF 12/121 reads (10%) | catalogued as rs782636374, COSV100971740, COSV65343482; called by mutect2, varscan2
- PEAK1 | c.886C>T p.L296= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as COSV56935574; called by muse, mutect2
- PGBD2 | c.1209T>C p.D403= | Silent (SNP) | VAF 8/185 reads (4%) | called by muse, mutect2
- PI16 | c.546G>A p.P182= | Silent (SNP) | VAF 25/147 reads (17%) | catalogued as rs776547275, COSV101028606; called by muse, mutect2, varscan2
- PKDREJ | c.2931C>A p.S977= | Silent (SNP) | VAF 18/200 reads (9%) | catalogued as COSV99478439; called by muse, mutect2
- PLCL1 | c.1173T>C p.P391= | Silent (SNP) | VAF 13/153 reads (8%) | catalogued as COSV101406798; called by muse, mutect2
- PLEKHM3 | c.2205G>A p.K735= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV70135991; called by muse, mutect2
- PON2 | c.972G>A p.G324= | Silent (SNP) | VAF 11/199 reads (6%) | catalogued as COSV56002160; called by muse, mutect2
- PRMT5 | c.18C>T p.V6= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs144489847; called by muse, mutect2, varscan2
- PTX4 | c.477C>T p.G159= (on ENST00000447419 / NM_001328608.2; = p.G154= on NM_001013658.1) | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV53516916; called by muse, mutect2
- RGS12 | c.1227C>T p.D409= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as rs778973905; called by muse, mutect2, varscan2
- RPA1 | c.1470G>A p.V490= | Silent (SNP) | VAF 18/223 reads (8%) | called by muse, mutect2
- RUVBL2 | c.384C>T p.G128= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as rs760854037, COSV99669211; called by muse, mutect2, varscan2
- SCUBE2 | c.651T>C p.C217= | Silent (SNP) | VAF 6/99 reads (6%) | catalogued as rs1302863536; called by muse, mutect2
- SDK2 | c.4449C>T p.G1483= | Silent (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2, varscan2
- SF3B1 | c.849C>T p.G283= | Silent (SNP) | VAF 13/155 reads (8%) | catalogued as rs747909166, COSV100133869; called by muse, mutect2
- SHQ1 | c.438C>T p.C146= | Silent (SNP) | VAF 21/202 reads (10%) | catalogued as rs1174576635, COSV100344559; called by muse, mutect2, varscan2
- SLC12A3 | c.801G>A p.S267= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs201871800, COSV52637472; called by mutect2, varscan2
- SLC25A29 | c.321C>T p.C107= (on ENST00000359232 / NM_001039355.3; = p.C41= on NM_152333.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100821085; called by muse, mutect2
- SPTA1 | c.6921G>A p.L2307= | Silent (SNP) | VAF 7/175 reads (4%) | catalogued as COSV63748987; called by muse, mutect2
- SRCAP | c.5175A>G p.V1725= | Silent (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- SRGAP3 | c.2796C>T p.S932= | Silent (SNP) | VAF 16/230 reads (7%) | catalogued as rs199643153, COSV64531624; called by muse, mutect2
- STMN4 | c.177C>A p.T59= (on ENST00000265770 / NM_001283054.2; = p.T86= on NM_030795.4) | Silent (SNP) | VAF 12/209 reads (6%) | catalogued as COSV56109110, COSV56109190, COSV56109902; called by muse, mutect2
- SUGP1 | c.1464G>A p.E488= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99894658; called by muse, mutect2, varscan2
- SUGP2 | c.717G>T p.G239= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as rs1206171371; called by muse, mutect2
- SYT16 | c.300C>T p.D100= | Silent (SNP) | VAF 26/202 reads (13%) | called by muse, mutect2, varscan2
- TANC2 | c.5001C>T p.I1667= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as rs935165801, COSV67335003; called by muse, mutect2
- TIMM23 | c.228C>A p.A76= | Silent (SNP) | VAF 70/690 reads (10%) | called by muse, mutect2, varscan2
- TMEM248 | c.918C>T p.P306= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs375502371; called by muse, mutect2, varscan2
- TMEM45B | c.115C>T p.L39= | Silent (SNP) | VAF 14/215 reads (7%) | called by muse, mutect2
- TNFSF8 | c.246C>T p.C82= | Silent (SNP) | VAF 5/102 reads (5%) | catalogued as COSV56342680; called by muse, mutect2
- TREX2 | c.201G>A p.E67= (on ENST00000334497; = p.E24= on NM_080701.3) | Silent (SNP) | VAF 18/180 reads (10%) | called by muse, mutect2
- TRIM41 | c.228G>A p.V76= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as rs1327128230, COSV100162949; called by muse, mutect2
- TSPAN15 | c.249G>A p.A83= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as rs368226985, COSV64783820; called by muse, mutect2
- TTN | c.6972G>A p.T2324= (on ENST00000591111; = p.T2278= on NM_003319.4) | Silent (SNP) | VAF 14/175 reads (8%) | catalogued as rs772147880, COSV60295970; ClinVar: likely benign; called by muse, mutect2
- UCK1 | c.327G>A p.T109= | Silent (SNP) | VAF 29/231 reads (13%) | catalogued as rs768154354; called by muse, mutect2, varscan2
- UGT1A8 | c.78G>A p.G26= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV65085624; called by muse, mutect2
- UNC13B | c.4506G>A p.E1502= | Silent (SNP) | VAF 16/148 reads (11%) | called by muse, mutect2
- USP42 | c.3783C>T p.V1261= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as rs967275897; called by muse, mutect2
- WDR81 | c.2211G>A p.T737= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs1405472649, COSV100488877; called by muse, mutect2
- ZBP1 | c.954C>T p.A318= | Silent (SNP) | VAF 16/128 reads (13%) | catalogued as rs146958594; called by muse, mutect2, varscan2
- ZNF30 | c.762C>T p.H254= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as rs1468643134; called by muse, mutect2, varscan2
- ZNF451 | c.300T>C p.N100= | Silent (SNP) | VAF 13/134 reads (10%) | catalogued as rs1381719266; called by muse, varscan2
- ZNF766 | c.1173C>T p.V391= | Silent (SNP) | VAF 9/129 reads (7%) | called by muse, mutect2
- ZNF98 | c.726G>A p.E242= | Silent (SNP) | VAF 14/222 reads (6%) | catalogued as COSV63336844; called by muse, mutect2
- ABCA2 | c.6264+56del | Intron (DEL) | VAF 5/37 reads (14%) | catalogued as rs772519279; called by mutect2, pindel
- ARL6 | c.*25C>T | 3'UTR (SNP) | VAF 14/226 reads (6%) | catalogued as COSV100256386; called by muse, mutect2
- COX14 | c.*168A>T | 3'UTR (SNP) | VAF 18/178 reads (10%) | catalogued as COSV100521087; called by muse, mutect2
- CXCR2 | c.*1151G>C | 3'UTR (SNP) | VAF 12/166 reads (7%) | catalogued as COSV100578838; called by muse, mutect2
- DCTN3 | c.412-9G>A | Intron (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- FLRT2 | c.*864del | 3'UTR (DEL) | VAF 7/77 reads (9%) | called by mutect2, pindel, varscan2
- GDI2 | c.45+1333del | Intron (DEL) | VAF 8/85 reads (9%) | called by mutect2, varscan2
- GLUD2 | c.*24C>T | 3'UTR (SNP) | VAF 16/227 reads (7%) | catalogued as COSV100046620; called by muse, mutect2
- GNA12 | c.526-29153G>A | Intron (SNP) | VAF 39/282 reads (14%) | catalogued as COSV51743712; called by muse, mutect2, varscan2
- ICAM1 | c.-6C>A | 5'UTR (SNP) | VAF 8/94 reads (9%) | catalogued as COSV99320514; called by muse, mutect2
- IVL | c.*21C>T | 3'UTR (SNP) | VAF 14/173 reads (8%) | catalogued as rs1273706430, COSV100908118; called by muse, mutect2
- KLHDC7B | c.*998T>C | 3'UTR (SNP) | VAF 10/100 reads (10%) | catalogued as COSV101192890; called by muse, mutect2
- LINC00205 | n.3213C>T | RNA (SNP) | VAF 8/105 reads (8%) | catalogued as rs1250543058; called by muse, mutect2
- LINC01555 | n.454A>G | RNA (SNP) | VAF 11/196 reads (6%) | called by muse, mutect2
- LINC01644 | n.423del | RNA (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- NHSL2 | c.*12C>T | 3'UTR (SNP) | VAF 11/119 reads (9%) | catalogued as rs1425126182, COSV101029890; called by muse, mutect2
- PABPC5 | c.*1134A>T | 3'UTR (SNP) | VAF 6/56 reads (11%) | catalogued as COSV100442130; called by muse, mutect2, varscan2
- RAG1 | c.*386del | 3'UTR (DEL) | VAF 5/45 reads (11%) | catalogued as rs886048258; ClinVar: uncertain significance; called by mutect2, pindel
- S1PR3 | c.-148+3879_-148+3880del | Intron (DEL) | VAF 14/117 reads (12%) | called by mutect2, varscan2
- SLC25A52 | c.-150T>C | 5'UTR (SNP) | VAF 8/92 reads (9%) | catalogued as COSV99329349; called by muse, mutect2
- SLC37A3 | c.1327-13del | Intron (DEL) | VAF 14/119 reads (12%) | catalogued as rs747804386; called by mutect2, varscan2
- TOR4A | c.*2228C>T | 3'UTR (SNP) | VAF 9/88 reads (10%) | catalogued as COSV100677649, COSV100677705; called by muse, mutect2
- USP27X | c.*543del | 3'UTR (DEL) | VAF 14/162 reads (9%) | called by mutect2, pindel
- ZNF789 | c.152-1842A>G | Intron (SNP) | VAF 12/118 reads (10%) | called by muse, mutect2
